Somatic mutation profile of tumor specimen TCGA-CR-6474-01A (aliquot TCGA-CR-6474-01A-11D-1870-08) from TCGA case TCGA-CR-6474, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 51.6 years (18,840 days).
Specimen TCGA-CR-6474-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98e908e8-4774-43f2-89fe-00eb350e9d0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6474-10A (Blood Derived Normal), aliquot TCGA-CR-6474-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12501500-0fab-4779-8b67-b07871c5d009

The open-access MAF lists 107 somatic variants for this specimen: 80 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 24, Nonsense Mutation 6, Frame Shift Del 2, Intron 2, Frame Shift Ins 1, Splice Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 44/93 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1588G>T p.G530C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99287642; called by muse, mutect2, varscan2
- ABHD8 | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV99395416; called by muse, mutect2, varscan2
- AC013489.1 | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99183818; called by muse, mutect2, varscan2
- ADAMTS1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99535727; called by muse, mutect2, varscan2
- ADAMTS18 | c.1000A>C p.I334L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.601); catalogued as COSV99270825; called by muse, mutect2
- AFF3 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 35/234 reads (15%) | catalogued as COSV100417043; called by muse, mutect2, varscan2
- ARHGEF10L | c.1493A>G p.E498G | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99391763; called by muse, mutect2, varscan2
- ATP6V1C1 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101214784; called by muse, mutect2
- ATRN | c.1408C>G p.L470V | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV99496394; called by muse, mutect2
- CADM2 | c.638C>G p.T213S (on ENST00000407528 / NM_001167674.2; = p.T215S on NM_153184.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101052315; called by muse, mutect2, varscan2
- CAMTA1 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV57911865; called by muse, mutect2
- CEP290 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs779867970, CD139094, COSV57124183; called by muse, mutect2, varscan2
- CFAP94 | c.191G>T p.R64M (on ENST00000320267 / NM_001352064.2; = p.R70M on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100208747; called by muse, mutect2, varscan2
- CLIP2 | c.1790A>G p.D597G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV99790821; called by muse, mutect2, varscan2
- CLIP2 | c.2462C>T p.T821M | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782465626, COSV56275416; called by muse, mutect2, varscan2
- COPRS | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 30/317 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100188312; called by muse, mutect2
- CPSF7 | c.28A>T p.I10L (on ENST00000394888 / NM_001136040.4; = p.I53L on NM_024811.4) | Missense Mutation (SNP) | VAF 38/281 reads (14%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.785); catalogued as COSV100073842; called by muse, mutect2, varscan2
- DDX46 | c.1445G>C p.G482A | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100844824; called by muse, mutect2, varscan2
- DPYD | c.1611G>T p.M537I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.076); catalogued as COSV100928355; called by muse, mutect2
- EBF3 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 29/172 reads (17%) | catalogued as COSV100798941, COSV62473667; called by muse, mutect2, varscan2
- EGFLAM | c.2986G>C p.D996H (on ENST00000354891 / NM_001205301.2; = p.D988H on NM_152403.4) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100379579, COSV100379862, COSV59303319; called by muse, mutect2, varscan2
- FAM184A | c.2026G>C p.D676H | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.324); catalogued as COSV100137253; called by muse, mutect2, varscan2
- FCRL5 | c.1797G>A p.W599* | Nonsense Mutation (SNP) | VAF 22/112 reads (20%) | catalogued as COSV100708380; called by muse, mutect2, varscan2
- FRY | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV100968680; called by muse, mutect2, varscan2
- GK5 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs751750142, COSV67487211; called by muse, mutect2, varscan2
- GRM1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV99263320; called by muse, mutect2, varscan2
- HACL1 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1162384938, COSV100337103; called by muse, mutect2
- HCRTR2 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100904056; called by muse, mutect2
- HS2ST1 | c.535T>C p.F179L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100777598; called by muse, mutect2
- IGHD | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101162779; called by muse, mutect2
- KALRN | c.7624G>C p.D2542H (on ENST00000360013 / NM_001024660.4; = p.D845H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99360777; called by muse, mutect2, varscan2
- KIF16B | c.3066C>G p.H1022Q | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as COSV100733589, COSV61718194; called by muse, mutect2
- KIFAP3 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV100846651; called by muse, mutect2
- KLHL4 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753507160, COSV100909004; called by muse, mutect2
- L3MBTL3 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs988382680, COSV100695635; called by muse, mutect2, varscan2
- LDHAL6B | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.211); catalogued as COSV99893923; called by muse, mutect2, varscan2
- LIMA1 | c.1363G>A p.G455S | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV100372140; called by muse, mutect2
- MAP2K2 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568260052, COSV53565047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MASP2 | c.1270G>T p.E424* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV101279967; called by muse, mutect2, varscan2
- MATK | c.755G>A p.G252D (on ENST00000310132 / NM_139355.3; = p.G253D on NM_002378.4) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100035753; called by muse, mutect2
- MDN1 | c.6858C>T p.F2286= | Splice Region (SNP) | VAF 12/149 reads (8%) | catalogued as COSV65522063; called by muse, mutect2
- MKI67 | c.2578G>C p.D860H | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.621); catalogued as COSV100896010; called by muse, mutect2
- MORF4L1 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.277); catalogued as COSV100489001; called by muse, mutect2, varscan2
- MYH6 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100676161; called by muse, mutect2, varscan2
- MYH8 | c.5699G>C p.R1900P | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770787118, COSV101238060; called by muse, varscan2
- MYO10 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.762); catalogued as COSV101569734; called by muse, mutect2, varscan2
- MYO3A | c.4449A>T p.K1483N | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.153); catalogued as COSV99777673; called by muse, mutect2
- NCKIPSD | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs777388211, COSV99583583; called by muse, mutect2
- NDST4 | c.1768A>C p.T590P | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV99995109; called by muse, mutect2, varscan2
- NEURL4 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100223718; called by muse, mutect2, varscan2
- NEXN | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV99630115; called by muse, mutect2
- NLRP8 | c.2191C>G p.Q731E | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.127); catalogued as COSV99404519; called by muse, mutect2, varscan2
- NRSN1 | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV101027181; called by muse, mutect2
- OR5M8 | c.426C>A p.F142L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV100510501; called by muse, mutect2, varscan2
- PKN2 | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV100281235; called by muse, mutect2, varscan2
- PLCB1 | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV100568965; called by muse, mutect2, varscan2
- RPS6KA6 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 16/23 reads (70%) | catalogued as COSV53121936; called by muse, mutect2, varscan2
- SCN1A | c.2194C>A p.Q732K (on ENST00000303395 / NM_001202435.3; = p.Q721K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV100318817; called by muse, mutect2, varscan2
- SETBP1 | c.896C>G p.P299R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV99951601; called by muse, mutect2, varscan2
- SFMBT2 | c.11C>G p.T4S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV100738242; called by muse, mutect2, varscan2
- SIL1 | c.1030-1G>C p.X344_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99497529, COSV99498203; called by muse, mutect2, varscan2
- SIPA1L1 | c.3370A>T p.R1124W | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV100664986; called by muse, mutect2, varscan2
- SLC1A4 | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99308757; called by muse, mutect2, varscan2
- SLC25A51 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs1025540609, COSV99643232; called by muse, mutect2, varscan2
- SLC35B2 | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99240792; called by muse, mutect2, varscan2
- SLIT2 | c.503A>T p.D168V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99879826; called by muse, mutect2, varscan2
- SPATA16 | c.1122G>T p.W374C | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100650765; called by muse, mutect2, varscan2
- THBS1 | c.2587G>A p.D863N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1323013562, COSV99527425; called by muse, varscan2
- TMC2 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 14/87 reads (16%) | catalogued as COSV100727257; called by muse, mutect2, varscan2
- TRIP12 | c.3194C>T p.A1065V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as rs750369222, COSV52264321, COSV99389009; called by muse, mutect2, varscan2
- TTN | c.24292G>A p.A8098T (on ENST00000591111; = p.A7171T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | PolyPhen possibly damaging (0.665); catalogued as rs1229032409, COSV100589283; called by muse, mutect2, varscan2
- USP33 | c.1957C>G p.Q653E | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as rs1463939654, COSV100656976; called by muse, mutect2
- USP53 | c.2543C>G p.S848C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV99917419; called by muse, mutect2, varscan2
- WDR90 | c.1585C>T p.R529W | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1482053044, COSV99553808; called by muse, mutect2
- ZIM3 | c.1067T>G p.I356S | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); catalogued as COSV99517497; called by muse, mutect2, varscan2
- ZNF493 | c.313A>T p.T105S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.312); catalogued as COSV100828496; called by muse, mutect2, varscan2
- CHD2 | c.1413_1449del p.K471Nfs*7 | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by mutect2, pindel
- PLCL1 | c.2834_2835del p.L945Rfs*27 | Frame Shift Del (DEL) | VAF 34/277 reads (12%) | called by mutect2, pindel, varscan2
- PRKCD | c.1460dup p.K488Qfs*26 | Frame Shift Ins (INS) | VAF 20/110 reads (18%) | called by mutect2, pindel, varscan2
- CD1D | c.171C>T p.S57= | Silent (SNP) | VAF 53/207 reads (26%) | catalogued as COSV100939517; called by muse, mutect2, varscan2
- CD22 | c.1491C>T p.V497= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as rs1315247320, COSV99322699; called by muse, mutect2, varscan2
- DOCK10 | c.5439A>G p.L1813= | Silent (SNP) | VAF 77/268 reads (29%) | catalogued as rs777106255, COSV99287112; called by muse, mutect2, varscan2
- FBXO4 | c.511C>T p.L171= | Silent (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- FLII | c.885G>A p.K295= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV100493388; called by muse, mutect2, varscan2
- H3C13 | c.324G>C p.T108= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100516005, COSV58944522; called by muse, mutect2, varscan2
- INTS1 | c.2310G>A p.V770= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101247288; called by muse, mutect2
- KCNAB1 | c.165C>G p.L55= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV101050731; called by muse, mutect2, varscan2
- KRTAP10-11 | c.480C>T p.T160= | Silent (SNP) | VAF 91/259 reads (35%) | catalogued as COSV100551369; called by muse, mutect2, varscan2
- LRRC4C | c.337A>C p.R113= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV53427082, COSV99536568; called by muse, mutect2, varscan2
- MARF1 | c.4704C>G p.L1568= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100705560; called by muse, mutect2, varscan2
- MNT | c.579A>C p.P193= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99437880; called by muse, mutect2, varscan2
- MRM3 | c.603G>A p.K201= | Silent (SNP) | VAF 16/223 reads (7%) | catalogued as COSV100444215; called by muse, mutect2
- MUC6 | c.1521C>A p.L507= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV101424322; called by muse, mutect2, varscan2
- NUTM1 | c.2328A>G p.L776= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV100148778; called by muse, mutect2, varscan2
- OR2F2 | c.606T>G p.S202= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV101283787; called by muse, mutect2, varscan2
- PPP6R2 | c.1098C>T p.C366= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV99323695; called by muse, mutect2, varscan2
- SFXN4 | c.444C>T p.F148= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV100340886; called by muse, mutect2, varscan2
- SLC3A2 | c.1575G>T p.R525= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV100101148, COSV58603525; called by muse, mutect2, varscan2
- SPAG16 | c.1729T>C p.L577= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100435041; called by muse, mutect2, varscan2
- TRAM1 | c.1002G>C p.V334= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99140689; called by mutect2, varscan2
- WDFY3 | c.1056A>T p.P352= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99881467; called by muse, mutect2
- WRAP53 | c.201A>G p.L67= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV99357491; called by muse, mutect2, varscan2
- ZNF721 | c.1857G>A p.Q619= (on ENST00000338977; = p.Q631= on NM_133474.4) | Silent (SNP) | VAF 36/372 reads (10%) | catalogued as COSV100166857; called by muse, mutect2
- FMN1 | c.2044-1611A>T | Intron (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100567763; called by muse, mutect2, varscan2
- RGS3 | c.3081-274G>A | Intron (SNP) | VAF 15/76 reads (20%) | catalogued as rs747060935, COSV100636516; called by muse, mutect2, varscan2
- ZNF99 | c.*122T>C | 3'UTR (SNP) | VAF 8/76 reads (11%) | catalogued as rs761910209, COSV101233623; called by muse, mutect2, varscan2
